CGCI case HTMCP-02-25-01216 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1b7e8533-e098-442d-b356-83b284c327fb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Dead; Days to death: 325 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 52.0 years (18,985 days); Year of diagnosis: 2003; Method of diagnosis: Incisional Biopsy; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 324 days.
   Pathology details: Lymph nodes positive: 1; Lymph nodes tested: 15.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 324 days; Disease response: With Tumor.
- Follow-up contacts recording only the day: day -5,683, day 0.

Molecular and laboratory tests
- NKX2-1 (IHC): Positive.
- Test (IHC): Negative; Specialized molecular test: P40.

Other clinical attributes
- Day -5,683: Risk factors: HIV/AIDS.
- Day -5,683: Comorbidities: HIV/AIDS.
- Day 0: CD4 count: 272; Haart treatment indicator: Yes; HIV viral load: 4484.
- Day 0: Comorbidities: Epstein-Barr Virus.
- Day 0: Risk factors: Epstein-Barr Virus.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 30.

Biospecimens (3 samples)
- Sample HTMCP-02-25-01216-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-25-01216-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-25-01216-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Adenocarcinoma, Not Otherwise Specified; Tumor status: With tumor; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lost to follow-up: Yes; Tobacco smoking history indicator: 2; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- History of disease: Year of HIV diagnosis: 1988; Haart therapy at diagnosis: No; Haart therapy prior to diagnosis: Yes; History relevant infectious diagnosis: EBV.
- Primary pathology: Lymph nodes examined: Yes; Days from index date to tumor sample procurement: 54; Other pos node location: azygos.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-25-01216-01A-01E-11090:
- % tumour top: 80
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-25-01216-11A-01E-11090:
- % tumour top: 0
- % tumour bottom: 0

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-25-01216-01A-01S-11090:
- % tumour top: 80
- % tumour bottom: 80
